Somatic mutation profile of tumor specimen 0DTGDA from CCDI case PBCJIC, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Rhabdomyosarcoma, NOS; Tissue or organ of origin: External ear; Age at diagnosis: 7.2 years (2,624 days).
Specimen 0DTGDA: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 231624e8-afd8-4e26-935a-3bef06d0bdde.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DTGDF (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/813bf876-a3a0-4037-ba6e-0fe6feed9f6d

The open-access MAF lists 52 somatic variants for this specimen: 35 protein-altering or splice-affecting, 11 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 11, Intron 3, Splice Site 2, 3'UTR 1, Splice Region 1, RNA 1, 5'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR4 | c.1648G>T p.V550L | Missense Mutation (SNP) | VAF 366/796 reads (46%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV52800715, COSV52802492, COSV52804538; called by muse, mutect2, varscan2
- ADGRF1 | c.944T>C p.V315A | Missense Mutation (SNP) | VAF 309/1096 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1561869157; called by muse, mutect2, varscan2
- ATP4A | c.12+1G>A p.X4_splice | Splice Site (SNP) | VAF 153/723 reads (21%) | catalogued as rs370980463; called by muse, mutect2, varscan2
- COMMD5 | c.404G>A p.R135Q | Missense Mutation (SNP) | VAF 171/1050 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as rs747513620, COSV57384357; called by muse, mutect2, varscan2
- EPHB2 | c.262G>A p.V88M | Missense Mutation (SNP) | VAF 233/775 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs764400386, COSV65859720; called by muse, mutect2, varscan2
- FAXC | c.586G>A p.E196K | Missense Mutation (SNP) | VAF 302/1001 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67601369, COSV67603807; called by muse, mutect2, varscan2
- GALNT16 | c.1556G>A p.G519E | Missense Mutation (SNP) | VAF 256/867 reads (30%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.72); catalogued as rs267604039; called by muse, mutect2, varscan2
- KCNH4 | c.2855C>T p.T952M | Missense Mutation (SNP) | VAF 353/1789 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.68); catalogued as rs745888215, COSV52917524; called by muse, mutect2, varscan2
- KIF26B | c.2689C>A p.Q897K | Missense Mutation (SNP) | VAF 267/890 reads (30%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.451); catalogued as COSV63653693, COSV63654236; called by muse, mutect2, varscan2
- SYNE1 | c.18266G>A p.R6089H (on ENST00000367255 / NM_182961.4; = p.R6018H on NM_033071.3) | Missense Mutation (SNP) | VAF 429/1516 reads (28%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as rs752053839, COSV54992855; called by muse, mutect2, varscan2
- TRPS1 | c.292C>T p.P98S (on ENST00000220888 / NM_001330599.2; = p.P111S on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 292/2231 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV99631134; called by muse, mutect2, varscan2
- ADGRA2 | c.2083G>A p.V695M | Missense Mutation (SNP) | VAF 213/1874 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- AGO2 | c.521A>G p.Y174C | Missense Mutation (SNP) | VAF 104/732 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by mutect2, varscan2
- AUTS2 | c.1853C>A p.A618D | Missense Mutation (SNP) | VAF 313/1498 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- BORA | c.278G>A p.R93K (on ENST00000613797; = p.R18K on NM_024808.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 328/1089 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- CD276 | c.664G>T p.V222L | Missense Mutation (SNP) | VAF 295/1111 reads (27%) | SIFT tolerated (0.59); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DDX54 | c.1233C>G p.I411M | Missense Mutation (SNP) | VAF 174/2116 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- FMN2 | c.2110G>T p.V704L | Missense Mutation (SNP) | VAF 269/1059 reads (25%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- GPR42 | c.140C>A p.P47Q | Missense Mutation (SNP) | VAF 499/2558 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by mutect2, varscan2
- KCNG2 | c.101C>A p.A34E | Missense Mutation (SNP) | VAF 230/678 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- KIAA2012 | c.811G>A p.D271N | Missense Mutation (SNP) | VAF 374/1629 reads (23%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.625); called by muse, mutect2, varscan2
- MUC5B | c.11047C>T p.P3683S | Missense Mutation (SNP) | VAF 291/1120 reads (26%) | SIFT tolerated (0.36); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- MYCBPAP | c.205-1G>A p.X69_splice | Splice Site (SNP) | VAF 516/1130 reads (46%) | called by muse, mutect2, varscan2
- MYH3 | c.3955C>A p.Q1319K | Missense Mutation (SNP) | VAF 529/1635 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.41); called by muse, mutect2, varscan2
- MYO16 | c.190C>A p.L64I | Missense Mutation (SNP) | VAF 129/1102 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PLEKHM1 | c.547G>T p.A183S | Missense Mutation (SNP) | VAF 303/1399 reads (22%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- POU4F3 | c.495C>A p.H165Q | Missense Mutation (SNP) | VAF 195/630 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.26); called by muse, mutect2, varscan2
- SFRP4 | c.998A>G p.K333R | Missense Mutation (SNP) | VAF 480/2130 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- SLC10A4 | c.938C>A p.A313D | Missense Mutation (SNP) | VAF 421/1352 reads (31%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.462); called by muse, mutect2, varscan2
- SLC25A43 | c.1014dup p.P339Tfs*27 | Frame Shift Ins (INS) | VAF 540/876 reads (62%) | called by mutect2, varscan2
- SLC41A2 | c.247C>A p.H83N | Missense Mutation (SNP) | VAF 332/1589 reads (21%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.508); called by muse, mutect2, varscan2
- SNRNP200 | c.3838A>G p.T1280A | Missense Mutation (SNP) | VAF 269/1193 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- TAOK2 | c.2361A>C p.R787S | Missense Mutation (SNP) | VAF 232/737 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.204); called by muse, mutect2, varscan2
- TRPV5 | c.1893G>C p.L631= | Splice Region (SNP) | VAF 256/1347 reads (19%) | called by muse, mutect2, varscan2
- ZC3HC1 | c.1136C>G p.T379S | Missense Mutation (SNP) | VAF 37/1424 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.937); called by muse, mutect2
- CCR3 | c.1062G>A p.V354= | Silent (SNP) | VAF 198/745 reads (27%) | called by muse, mutect2, varscan2
- CPA6 | c.643C>T p.L215= | Silent (SNP) | VAF 225/2247 reads (10%) | catalogued as COSV52743311; called by muse, mutect2, varscan2
- EHD4 | c.1356C>T p.D452= | Silent (SNP) | VAF 116/1108 reads (10%) | catalogued as rs746033503, COSV55007148; called by muse, mutect2
- EXOC3 | c.963G>A p.T321= | Silent (SNP) | VAF 396/1240 reads (32%) | catalogued as rs765761528; called by muse, mutect2, varscan2
- KRT72 | c.1320C>T p.G440= | Silent (SNP) | VAF 274/1266 reads (22%) | catalogued as rs140936315; called by muse, mutect2, varscan2
- NISCH | c.120C>A p.G40= | Silent (SNP) | VAF 161/628 reads (26%) | called by muse, mutect2, varscan2
- RBMY1A1 | c.1351A>C p.R451= | Silent (SNP) | VAF 82/804 reads (10%) | called by mutect2, varscan2
- RYR1 | c.14994C>T p.N4998= | Silent (SNP) | VAF 210/1181 reads (18%) | called by muse, mutect2, varscan2
- SLC2A14 | c.510G>A p.S170= | Silent (SNP) | VAF 299/1581 reads (19%) | catalogued as rs757745238, COSV61588705; called by muse, mutect2, varscan2
- VWDE | c.1893G>A p.A631= | Silent (SNP) | VAF 543/2275 reads (24%) | catalogued as rs1473804908, COSV51719816; called by muse, mutect2, varscan2
- ZFHX4 | c.3018T>C p.Y1006= | Silent (SNP) | VAF 457/3494 reads (13%) | catalogued as rs929984478; called by muse, mutect2, varscan2
- CTNNA2 | c.2190-73C>A | Intron (SNP) | VAF 56/257 reads (22%) | catalogued as COSV100561238; called by muse, mutect2, varscan2
- GATB | c.*88G>T | 3'UTR (SNP) | VAF 16/406 reads (4%) | called by muse, mutect2
- GTPBP3 | chr19:17334970 C>A | 5'Flank (SNP) | VAF 238/1034 reads (23%) | catalogued as rs934924117; called by muse, mutect2, varscan2
- MTSS1 | c.1405-58A>C | Intron (SNP) | VAF 42/450 reads (9%) | called by muse, mutect2
- MUC19 | n.16808_16809insC | RNA (INS) | VAF 247/1456 reads (17%) | called by mutect2, varscan2
- USP40 | c.2381-58G>T | Intron (SNP) | VAF 18/414 reads (4%) | called by muse, mutect2
